Surgical pathology report (de-identified scan), TCGA case TCGA-W2-A7HH, project TCGA-PCPG (Pheochromocytoma and Paraganglioma), tissue source site Medical College of Wisconsin, specimen TCGA-W2-A7HH-01A (Primary Tumor).

[page 1 of 2]
Results History

SURG PATH FINAL REPORT

Entry Information

Entry Date and Time

Lab Status
Final result

Entered by

Component Results

SURG PATH FINAL REPORT:

Accession #:

Specimen:

Date of Procedure:

Performing Clinician:

A. Right adrenal and paraganglioma

Clinical Notes:

Paraganglioma. A) Fresh tissue saved for bank.

tissue

Diagnosis:

- A. Right adrenal gland, excision:
- Adrenal cortical adenoma (1.8 cm).
- Paraganglioma (2.2 cm).

IMMUNOHISTOCHEMISTRY DISCLAIMER: This test was developed and its performance characteristics determined by

It has not been cleared or approved by the U.S. Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary. By placing the electronic signature on this report, the pathologist certifies that all positive and negative immunohistochemistry controls were reviewed and approved.

(Electronically signed by)

Verified:

Gross:

A. The specimen is labeled "right adrenal and paraganglioma." Received fresh in and transferred to formalin is a 46.2 gram, 10.5 x 5.5 x 1.5 cm, adrenal gland with attached yellow lobulated adipose tissue. The outer surface is inked black and the specimen is serially sectioned to reveal a well encapsulated 1.8 x 1.2 x 1.2 cm soft yellow-tan nodule attached to a 4.5 x 2.4 x 0.6 cm adrenal gland with grossly unremarkable yellow cortex. The central tan medulla appears slightly expanded. Additionally

ICD-O-3
Paraganglioma, extraadrenal
8693/1
Site Periadrenal tissue
248.0
JW 9/4/13

[page 2 of 2]
[REDACTED]

within the yellow lobulated adipose tissue there is a 2.2 x 1.6 x 1.3 cm soft, pink to slightly orange, well-circumscribed, soft nodule. Representative sections are submitted as follows:

Cassette Designation:

Accession #:

A1-3	Adrenal nodule
A4-5	Nodule in adipose tissue
A6-8	Adrenal gland

Microscopic:

A histological examination has been performed.

A. Sections show a diffusely enlarged adrenal gland with expanded medulla and a 1.8 cm nodule predominantly composed of clear cells resembling zona fasciculata cells, consistent with adrenal cortical adenoma. There is no evidence of increased mitoses, necrosis, or capsular or vascular invasion. Additionally, there is a 2.2 cm nodule within the adjacent adipose tissue. Sections show an unremarkable ganglion with an adjacent well circumscribed lesion composed of nests and trabeculae of bland cells with abundant granular cytoplasm and round nuclei with coarse chromatin within a rich, vascular network. Immunostains for Synaptophysin and Chromogranin show positive staining within the tumor cells while S-100 protein highlights the sustentacular cell network. There is no evidence of increased mitoses, necrosis, or vascular or capsular invasion.

Administrative Notes:

CPT:

No charge codes are associated with this case.

IIA Discrepancy		☒

Entry Information

Entry Date and Time

Lab Status
In process

Entered by

Source: NCI Genomic Data Commons file e5df62ce-49a9-4417-9021-81d526e2bdf1 (TCGA-W2-A7HH.1DFB5218-671E-4CB1-BE19-2E338EA7B057.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).